Somatic mutation profile of tumor specimen BA3242D (aliquot aq-BA3242D) from BEATAML1.0 case 2805, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,756 days).
Specimen BA3242D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5b4a0f-27ec-48ff-9593-78e761d496f2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3274D (Solid Tissue Normal), aliquot aq-BA3274D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd5a80c-568c-4d6b-aa38-e529c885df89

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN2 | c.3138G>C p.K1046N | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52489763; called by muse, mutect2
- NINL | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1348498999, COSV54001513, COSV99625992; called by muse, mutect2
- SHANK1 | c.2529C>G p.G843= | Silent (SNP) | VAF 21/295 reads (7%) | called by muse, mutect2
